Somatic mutation profile of tumor specimen MMRF_1107_1_BM_CD138pos (aliquot MMRF_1107_1_BM_CD138pos_T2_TSE61_K03190) from MMRF case MMRF_1107, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.1 years (29,995 days).
Specimen MMRF_1107_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60196e42-0ea9-4672-9ed4-805ba592f4e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1107_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1107_1_PB_Whole_C1_TSE61_K03193; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e60e3d8-b3b3-4a40-a7ef-06f583a6f018

The open-access MAF lists 118 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 42, Missense Mutation 39, Silent 15, 3'Flank 4, Nonsense Mutation 4, 5'Flank 3, 5'UTR 3, Intron 2, RNA 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA2 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs768890920; called by muse, mutect2, varscan2
- C1S | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs147971272; called by muse, mutect2, varscan2
- CELSR2 | c.6920G>A p.R2307H | Missense Mutation (SNP) | VAF 77/145 reads (53%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.793); catalogued as rs199671594; called by muse, mutect2, varscan2
- GNA11 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs756991534; called by muse, mutect2, varscan2
- ITGA1 | c.2497C>T p.R833* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as rs1284043705, COSV50882399; called by muse, mutect2, varscan2
- KIAA0319L | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs538303265; called by muse, mutect2, varscan2
- LMTK2 | c.1144A>G p.R382G | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs748842293; called by muse, mutect2, varscan2
- OBSL1 | c.4855G>T p.A1619S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.38); catalogued as COSV54705545; called by muse, mutect2
- OR1M1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs765053649, COSV70036933; called by muse, mutect2, varscan2
- PWWP2B | c.1670G>C p.R557P | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs762806412; called by muse, mutect2, varscan2
- RABGAP1L | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV52296384; called by muse, mutect2
- RALYL | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774438419, COSV72823376; called by muse, mutect2, varscan2
- RETREG2 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56087141; called by muse, mutect2, varscan2
- SEC31B | c.3400C>T p.R1134* | Nonsense Mutation (SNP) | VAF 53/101 reads (52%) | catalogued as rs146717788, COSV100648918; called by muse, mutect2, varscan2
- SLC22A2 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs567153149, COSV65266081; called by muse, mutect2, varscan2
- SLC39A12 | c.1438G>T p.V480F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.346); catalogued as rs368968698; called by muse, mutect2, varscan2
- TASP1 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs1252637385; called by muse, varscan2
- TM2D1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as rs747654236, COSV53908945; called by mutect2, varscan2
- TRMT13 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as COSV100924029; called by muse, mutect2, varscan2
- USP53 | c.1304T>C p.I435T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56792454; called by muse, mutect2, varscan2
- XIRP2 | c.2342A>G p.N781S (on ENST00000628543; = p.N956S on NM_152381.6) | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs767396950; called by muse, mutect2, varscan2
- ZFYVE9 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs376354655; called by muse, mutect2, varscan2
- ARHGAP11A | c.2583_2584insCCG p.A861_S862insP | In Frame Ins (INS) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
- ARHGAP39 | c.2953C>T p.Q985* (on ENST00000276826 / NM_001308208.2; = p.Q1016* on NM_025251.2) | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2, varscan2
- ARSD | c.1629G>T p.R543S | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CHEK1 | c.395A>C p.K132T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DBH | c.1759T>A p.S587T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.005); called by muse, mutect2
- DDO | c.595G>T p.V199L (on ENST00000368924 / NM_001368172.1; = p.V140L on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- DDX1 | c.170G>C p.S57T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FBP2 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FCER2 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2
- HOOK2 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- IL17RA | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LCOR | c.83C>A p.T28K | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MED13L | c.4285G>C p.A1429P | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- OR5T3 | c.528del p.F176Lfs*45 | Frame Shift Del (DEL) | VAF 168/389 reads (43%) | called by pindel, varscan2
- PARP16 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDS5A | c.1742G>T p.C581F | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PHF21A | c.770C>A p.P257H (on ENST00000418153 / NM_001101802.3; = p.P258H on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POM121L2 | c.2333C>T p.A778V | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2
- RDX | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SLC5A10 | c.1762A>C p.N588H (on ENST00000395645 / NM_001042450.4; = p.N604H on NM_152351.5) | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SLCO4A1 | c.1732C>A p.P578T | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SMPD2 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 47/142 reads (33%) | called by muse, mutect2, varscan2
- UBQLN2 | c.70del p.A24Lfs*14 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- UPRT | c.396T>G p.S132R | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZDHHC23 | c.67dup p.L23Pfs*22 | Frame Shift Ins (INS) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- ANLN | c.2859A>C p.G953= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- CAMK2A | c.1389G>A p.Q463= (on ENST00000348628 / NM_171825.2; = p.Q474= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- CDH7 | c.1071G>A p.P357= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs138826876, COSV59890298; called by muse, mutect2, varscan2
- CDHR5 | c.573G>A p.L191= | Silent (SNP) | VAF 92/208 reads (44%) | catalogued as rs1384402368, COSV62764196; called by muse, mutect2, varscan2
- EBF2 | c.264C>T p.F88= | Silent (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- NELL1 | c.1233T>C p.N411= | Silent (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- OSBP2 | c.1452C>T p.S484= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs540332661, COSV100213395, COSV60248509; called by muse, mutect2, varscan2
- PSMG1 | c.612A>G p.P204= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs200983810; called by muse, mutect2, varscan2
- SALL3 | c.1506G>A p.S502= | Silent (SNP) | VAF 40/175 reads (23%) | catalogued as rs774287520, COSV101609926; called by muse, mutect2, varscan2
- SEZ6L | c.1023C>T p.D341= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs888178964, COSV50661853; called by muse, mutect2, varscan2
- SLC28A2 | c.477T>G p.L159= | Silent (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- THY1 | c.138A>C p.S46= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- UNC93B1 | c.1752G>A p.P584= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as rs1163814751; called by muse, mutect2, varscan2
- ZNF775 | c.156G>T p.P52= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as COSV61614112; called by muse, mutect2, varscan2
- ZSCAN18 | c.1209C>T p.D403= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as rs1451098465; called by muse, mutect2, varscan2
- AC103796.1 | n.148-25416T>A | Intron (SNP) | VAF 28/70 reads (40%) | catalogued as rs1307979643; called by muse, mutect2, varscan2
- AC139495.2 | n.650T>G | RNA (SNP) | VAF 96/789 reads (12%) | called by mutect2, varscan2
- AGFG1 | c.*5152T>A | 3'UTR (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.*2384G>A | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.*2385G>T | 3'UTR (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- BDH2 | c.*192A>T | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576036 G>A | 5'Flank (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- BSN | c.*728C>A | 3'UTR (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- CDC20P1 | chr9:87010055 A>G | 5'Flank (SNP) | VAF 49/177 reads (28%) | called by muse, mutect2, varscan2
- CEP350 | c.*2928C>T | 3'UTR (SNP) | VAF 133/189 reads (70%) | called by muse, mutect2, varscan2
- CHST14 | c.*706T>G | 3'UTR (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2
- COL19A1 | c.*2363T>C | 3'UTR (SNP) | VAF 39/174 reads (22%) | called by muse, mutect2, varscan2
- COX20 | c.43-694A>T | Intron (SNP) | VAF 109/145 reads (75%) | called by muse, mutect2, varscan2
- CPLX3 | c.*632C>A | 3'UTR (SNP) | VAF 43/123 reads (35%) | called by muse, mutect2, varscan2
- EDAR | chr2:108989242 G>T | 5'Flank (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- EPHA3 | c.*1925A>T | 3'UTR (SNP) | VAF 54/80 reads (68%) | catalogued as rs908406690; called by muse, mutect2, varscan2
- FAM86C1P | n.545A>T | RNA (SNP) | VAF 195/375 reads (52%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1016T>A | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- GABRA1 | chr5:161897808 T>G | 3'Flank (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- GABRG2 | c.*1134C>A | 3'UTR (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- GPA33 | c.*608G>A | 3'UTR (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- GPR155 | chr2:174432105 del CT | 3'Flank (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- GRIK3 | c.*1538G>T | 3'UTR (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- HUWE1 | c.-254C>T | 5'UTR (SNP) | VAF 33/33 reads (100%) | called by muse, mutect2, varscan2
- IL6R | c.*1051_*1053del | 3'UTR (DEL) | VAF 21/89 reads (24%) | called by pindel, varscan2
- JPH3 | chr16:87700235 C>G | 3'Flank (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- KRTAP1-3 | c.*301C>T | 3'UTR (SNP) | VAF 31/63 reads (49%) | catalogued as rs917946726; called by muse, mutect2, varscan2
- LPCAT2 | c.*3262T>C | 3'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as rs1567410562; called by muse, mutect2, varscan2
- MORC2 | c.*901G>A | 3'UTR (SNP) | VAF 33/64 reads (52%) | catalogued as rs964188895; called by muse, mutect2, varscan2
- MSR1 | c.*378T>A | 3'UTR (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- NCCRP1 | c.*738A>C | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- NDUFS1 | c.-60G>A | 5'UTR (SNP) | VAF 56/97 reads (58%) | catalogued as rs1184995845; called by muse, mutect2, varscan2
- NEURL1B | c.*1743C>A | 3'UTR (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- NIBAN1 | c.*1753C>T | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- NLGN4X | c.*1546G>T | 3'UTR (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- NR2E1 | c.*921C>G | 3'UTR (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- NYNRIN | c.*87C>T | 3'UTR (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- PHLDB2 | c.*1510A>T | 3'UTR (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- PLVAP | c.*449G>A | 3'UTR (SNP) | VAF 53/85 reads (62%) | catalogued as rs1381055987; called by muse, mutect2, varscan2
- PPP1R12B | c.*627C>G | 3'UTR (SNP) | VAF 67/93 reads (72%) | called by muse, mutect2, varscan2
- PRKG1 | c.*243T>C | 3'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- RDH10 | c.*1098G>A | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- RIOK2 | c.*86A>C | 3'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- RNF222 | c.*95C>T | 3'UTR (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- RNF4 | c.*1106T>G | 3'UTR (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- RP2 | c.-16T>G | 5'UTR (SNP) | VAF 30/30 reads (100%) | called by muse, mutect2, varscan2
- SBSPON | c.*89C>A | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- SLC24A4 | c.*457G>T | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- SORBS1 | chr10:95314473 C>A | 3'Flank (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- SSU72 | c.*89G>A | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- STK35 | c.*2242T>A | 3'UTR (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- STK4 | c.*2515T>C | 3'UTR (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- SUMO3 | c.*269T>C | 3'UTR (SNP) | VAF 20/50 reads (40%) | catalogued as rs1204324365; called by muse, mutect2, varscan2
- VCPIP1 | c.*1058T>G | 3'UTR (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- YTHDC1 | c.*261T>A | 3'UTR (SNP) | VAF 23/48 reads (48%) | called by muse, mutect2, varscan2
- ZNF580 | c.*62C>A | 3'UTR (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99553130; called by muse, mutect2
